Somatic mutation profile of tumor specimen BA3088D (aliquot aq-BA3088D) from BEATAML1.0 case 2712, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.3 years (22,035 days).
Specimen BA3088D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 316a5a74-011d-4a02-890c-bccc0050e98c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3220D (Solid Tissue Normal), aliquot aq-BA3220D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/049ed568-9c29-417e-8974-e59ba4495164

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.929_930insCTTGGACCCTGCTCA p.T310_Q311insLDPAQ | In Frame Ins (INS) | VAF 20/133 reads (15%) | catalogued as COSV57195782, COSV57196897, COSV57198121, COSV57198241, COSV57198382, COSV57198801, COSV57200968; called by pindel, varscan2
